Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A6RR, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A6RR-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

Collection Date:

PART 1: ESOPHAGEAL STENT, REMOVAL -

- A. STENT (gross only).
- B. ATTACHED SQUAMOUS MUCOSA WITH INFLAMED GRANULATION TISSUE, NEGATIVE FOR MALIGNANCY.

PART 2: TISSUE NEAR LEFT BASE, GASTRIC, EXCISION -

FRAGMENT OF FIBROADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.

PART 3: TISSUE NEAR LEFT GASTRIC, EXCISION -

FIBROADIPOSE TISSUE WITH ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 4: INFERIOR PULMONARY LIGAMENT LYMPH NODES, EXCISION -

FIBROADIPOSE TISSUE WITH ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 5: LEVEL 7 LYMPH NODE NEAR BRONCHUS INTERMEDIUS, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 6: LYMPH NODE NEAR PERICARDIUM, EXCISION -

THREE LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/3).

PART 7: LYMPH NODES NEAR LOWER LOBE BRONCHUS, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 8: LYMPH NODE NEAR CARINA, EXCISION -

TWO LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/2).

PART 9: PARAESOPHAGEAL TISSUE, EXCISION -

METASTATIC ADENOCARCINOMA INVOLVING ONE OUT OF ONE LYMPH NODE (1/1).

PART 10: PARAESOPHAGEAL LYMPH NODE, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 11: PARAESOPHAGEAL LYMPH NODE NEAR LEFT PLEURA, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 12: PARAESOPHAGEAL LYMPH NODE, NEAR RIGHT MAIN BRONCHUS, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 13: LYMPH NODE NEAR LEFT VAGUS, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 14: LYMPH NODE NEAR RIGHT VAGUS, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 15: PARAESOPHAGEAL LYMPH NODE NEAR 30 CM, EXCISION -

METASTATIC ADENOCARCINOMA INVOLVING TWO OUT OF TWO LYMPH NODES (2/2).

PART 16: PARAESOPHAGEAL LYMPH NODE AT 25 CM, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 17, 23, 24, 25, & 26: ESOPHAGUS AND PROXIMAL STOMACH, GASTRIC RING, FINAL ESOPHAGEAL MARGIN, ANASTOMOTIC RINGS, AND FINAL GASTRIC MARGINS, ESOPHAGECTOMY -

- A. ULCERATED, INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, 7 CM, PRESENT AT MID TO DISTAL ESOPHAGUS WITH EXTENSION INTO GASTROESOPHAGEAL JUNCTION AND PROXIMAL CARDIA, ARISING FROM COLUMNAR MUCOSA WITH HIGH GRADE DYSPLASIA.
- B. THE CARCINOMA INVADES THROUGH THE MUSCULAR PROPRIA AND INFILTRATES INTO ESOPHAGEAL ADVENTITIA.
- C. POSITIVE FOR ANGIOLYMPHATIC INVASION AND VASCULAR INVASION.
- D. NO PERINEURAL INVASION IDENTIFIED.
- E. THE PROXIMAL MARGIN IS INVOLVED BY ADENOCARCINOMA. THE DISTAL SURGICAL RESECTION MARGIN IS FREE OF NEOPLASM AND DYSPLASIA. THE CIRCUMFERENTIAL (ADVENTITIA) CANNOT BE EVALUATED. (See comment).
- F. METASTATIC ADENOCARCINOMA INVOLVING TWO OUT OF SIX LYMPH NODES (2/6).
- G. AJCC PATHOLOGIC STAGING: pT3 N3 (See synoptic report).

PART 18: GASTROESOPHAGEAL FAT, EXCISION -

METASTATIC ADENOCARCINOMA INVOLVING TWO OUT OF SEVENTEEN LYMPH NODES (2/17).

PART 19: GASTRIC FAT LYMPH NODE, EXCISION -

METASTATIC ADENOCARCINOMA INVOLVING ONE OUT ONE LYMPH NODE (1/1).

PART 20: SUBCARINAL LYMPH NODE NEAR LEFT ATRIUM, EXCISION -

ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

ICD-O-3

Adenocarcinoma NOS
8140/3
Site CACF
gastroesophageal junction
CK6-D
path
distal third esophagus
C155

4/8/2013

[page 2 of 2]
PART 21: SUBCARINAL LYMPH NODE NEAR AZYGIOUS, EXCISION –
METASTATIC ADENOCARCINOMA INVOLVING ONE OUT OF ONE LYMPH NODE (1/1).

PART 22: SUBCARINAL LYMPH NODE, EXCISION –
ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 27: OMENTUM, OMENTECTOMY –
MATURE ADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.

COMMENT:

1. The anastomotic ring in part 25 is a portion of esophagus shows vascular invasion at the esophageal adventitia, confirmed by dual immunostain of AE1-AE3/CD31 and elastin stain (VVG). This is considered as positive proximal margin in the synoptic report. This finding was discussed with

2. The circumferential margin can't be accurately evaluated due to intraoperative peri-esophageal and peri-gastric fat stripping.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Tumor midpoint in distal esophagus AND tumor involves esophagogastric junction
TUMOR SIZE: Greatest dimension: 7 cm
Additional dimensions: 5 x 2 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3
PATHOLOGIC STAGING (pTNM)
pT3
pN3
Number of lymph nodes examined: 45
Number of lymph nodes involved: 9
17 or more regional lymph nodes were identified
pM Not applicable
No prior treatment

**PRIOR TREATMENT:
MARGINS**

Proximal margin involved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Distal margin uninvolved by dysplasia
Distal margin uninvolved by intestinal metaplasia
Circumferential (adventitial) margin cannot be assessed (see Comment)
Present

ANGIOLYMPHATIC INVASION:

ADDITIONAL PATHOLOGIC FINDINGS: High grade dysplasia

Comment:

Lymph nodes from the entire specimen are included in the synoptic report.
Adventitial margin can't be evaluated due to intraoperative stripping.

Source: NCI Genomic Data Commons file 56867122-fa19-4319-8fc1-6c4035aa2814 (TCGA-IN-A6RR.26F5CD91-58E0-45AC-BCF5-47AD99D3F569.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).